Somatic mutation profile of tumor specimen BA2143D (aliquot aq-BA2143D) from BEATAML1.0 case 2127, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Myelodysplastic syndrome, unclassifiable; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.8 years (18,934 days).
Specimen BA2143D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 728cd0c5-c2a1-4a5c-b0bd-441fd30d04db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2582D (Solid Tissue Normal), aliquot aq-BA2582D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a32e867-5145-41c3-ac96-a77a72eb9c81

The open-access MAF lists 15 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Intron 3, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDHGB3 | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as rs569737317, COSV53912080; called by muse, mutect2, varscan2
- SNTG1 | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV52447453; called by muse, mutect2
- CARMIL1 | c.2076C>A p.D692E | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); called by muse, mutect2
- FASN | c.4699dup p.Y1567Lfs*20 | Frame Shift Ins (INS) | VAF 17/89 reads (19%) | called by mutect2, pindel, varscan2
- SH2B2 | c.1563C>A p.H521Q | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2
- TIGD5 | c.1353C>A p.S451R | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); called by muse, mutect2
- TRMT2B | c.1397G>T p.C466F | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.18); called by muse, mutect2
- KCNC4 | c.852C>A p.I284= | Silent (SNP) | VAF 3/51 reads (6%) | called by muse, mutect2
- LGI1 | c.651G>A p.K217= | Silent (SNP) | VAF 23/180 reads (13%) | catalogued as rs1292925776; called by muse, mutect2, varscan2
- SLC16A8 | c.279G>T p.L93= | Silent (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- TOPAZ1 | c.2238C>T p.S746= | Silent (SNP) | VAF 28/94 reads (30%) | called by muse, mutect2, varscan2
- MLIP | c.613-11484G>A | Intron (SNP) | VAF 72/143 reads (50%) | catalogued as rs570107272; called by muse, varscan2
- OFCC1 | n.393-2900A>T | Intron (SNP) | VAF 28/135 reads (21%) | called by muse, mutect2, varscan2
- PDE10A | c.68-32857C>T | Intron (SNP) | VAF 28/143 reads (20%) | catalogued as rs1379280950, COSV100605192; called by muse, mutect2, varscan2
- ZFP36L1 | chr14:68796182 C>A | 5'Flank (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
